Somatic mutation profile of tumor specimen TARGET-40-NAAHBY-01A (aliquot TARGET-40-NAAHBY-01A-01D) from TARGET case TARGET-40-NAAHBY, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 15.2 years (5,538 days).
Specimen TARGET-40-NAAHBY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 646a4abb-fbc5-4397-922c-302f38194692.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAHBY-10A (Blood Derived Normal), aliquot TARGET-40-NAAHBY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59d7e2d0-6a37-4b03-ae47-d3918055d509

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.405C>G p.C135W | Missense Mutation (SNP) | VAF 84/155 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519976, COSV52665429, COSV52669330, COSV52682693, COSV52815283; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PLXNA3 | c.5203G>A p.V1735M | Missense Mutation (SNP) | VAF 64/253 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63754434, COSV63755672; called by muse, mutect2, varscan2
- PTPRD | c.4669G>A p.V1557I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DCC | c.870G>A p.L290= | Silent (SNP) | VAF 34/112 reads (30%) | called by muse, mutect2, varscan2
- DQX1 | c.1542C>G p.A514= | Silent (SNP) | VAF 79/319 reads (25%) | called by muse, mutect2, varscan2
- USP11 | c.1776C>G p.V592= (on ENST00000218348; = p.V549= on NM_001371072.1) | Silent (SNP) | VAF 111/371 reads (30%) | catalogued as rs1017110414; called by muse, mutect2, varscan2
- ZNF184 | c.1092T>C p.C364= | Silent (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
